Gene-level copy-number profile of tumor specimen TCGA-02-0034-01A from TCGA case TCGA-02-0034, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 60.7 years (22,166 days).
Specimen TCGA-02-0034-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.19b8fe45-1765-4b59-803a-e7a1e4aa9b4a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-02-0034-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/0e389d2e-a909-473d-9c6a-333d13cb603e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 17; copy number 1: 12,588; copy number 2: 44,166; copy number 3: 3,048.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-02-0034-01): tumor purity 0.52, ploidy 1.89, whole-genome doublings 0 (call status: snp_call).

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:79,611,418–79,974,169, 4 genes: AC008056.2, AC008056.3, AC008056.1, AF123462.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 10,214. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
